Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A22I, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A22I-01A (Primary Tumor).

[page 1 of 3]
ICD-0-3

Carcinoma, papillary, thyroid NOS 8260/3

Site: Thyroid, NOS C73.9

4/21/11
ju

Surgical Pathology Consultation Report

Patient

Name:

MRN:

DOB:

Gender: F

HCN:

Ordering

MD:

Copy To:

Service:

Visit #:

Location:

Facility:

Accession #:

Collected:

Received:

Reported:

Specimen(s) Received

1. Thyroid: Total Thyroid stich marks right upper pole - reg

Diagnosis

Widely invasive bilateral and multifocal papillary carcinoma involving surgical margins, dominant classical variant, 2.1 cm, left, with extrathyroidal extension and focal thyroiditis: Thyroid

Invasive papillary thyroid carcinoma: Parathyroid, 1 of 2, left

No pathological diagnosis: Parathyroid, left

No pathological diagnosis: Lymph node, isthmus

-Total thyroidectomy specimen.

Synoptic Data

Procedure:	Total thyroidectomy
Received:	Fresh
Specimen Integrity:	Intact
Specimen Size:	Right lobe:
	5.0 cm
	2.4 cm
	1.6 cm
	Left lobe:
	4.4 cm
	2.6 cm
	1.7 cm
	Isthmus +/- pyramidal lobe:
	3.6 cm
	1.2 cm
	0.7 cm
Specimen Weight:	17.7 g
Tumor Focality:	Multifocal, bilateral
	Multifocal, midline (isthmus)

----- DOMINANT TUMOR -----

IIIAA Discrepancy		X
Case is (check):		
Reviewed Initials	KMI	

[page 2 of 3]
Tumor Laterality:	Left lobe
Tumor Size:	Greatest dimension: 2.1cm Additional dimension: 2.1 cm Additional dimension: 1.6 cm
Histologic Type:	Papillary carcinoma, classical (usual) Classical (papillary) architecture Classical cytomorphology
Histologic Grade:	Not applicable
Margins:	Margin(s) involved by carcinoma
Tumor Capsule:	None
Tumor Capsular Invasion:	Present, extent widely invasive
Lymph-Vascular Invasion:	Indeterminate
Perineural Invasion:	Indeterminate
Extrathyroidal Extension:	Present, minimal
----- SECOND TUMOR -----	
Tumor Laterality:	Right lobe
Tumor Size:	Greatest dimension: 1.7cm Additional dimensions: 1.0 cm
Histologic Type:	Papillary carcinoma, classical (usual) Papillary carcinoma, follicular variant Classical (papillary) architecture Follicular architecture Classical cytomorphology
Histologic Grade:	Not applicable
Margins:	Margin(s) involved by carcinoma
Tumor Capsule:	None
Tumor Capsular Invasion:	Present, extent widely invasive
Lymph-Vascular Invasion:	Indeterminate
Perineural Invasion:	Not identified
Extrathyroidal Extension:	Not identified
TNM Descriptors:	m (multiple primary tumors)
Primary Tumor (pT):	pT3: Tumor more than 4 cm, limited to thyroid or with minimal extrathyroidal extension (eg, extension to sternothyroid muscle or perithyroid soft tissues)
Regional Lymph Nodes (pN):	pN0: No regional lymph node metastasis Number of regional lymph nodes examined: 1 Number of regional lymph nodes involved: 0
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	Thyroiditis, focal (nonspecific) Thyroiditis, palpation Parathyroid gland(s), within normal limits Parathyroid gland(s), other: infiltrated by papillary thyroid carcinoma. Other: additional papillary microcarcinoma, follicular variant, 0.7cm, seen in the isthmus.

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

[page 3 of 3]
Comment

There are multiple foci suspicious for vascular and perineural invasion but unequivocal evidence is not seen. The second dominant nodule extends through the painted margin whereas the dominant nodule extends right up to the margin.

verified by:

Electronically

Gross Description

The specimen labeled with the patient's name and as "total thyroid stitch marks right upper pole" consists of a thyroid gland that weighs 17.7 g (fresh). The right lobe measures 5.0 cm SI x 2.4 cm ML x 1.6 cm AP, the left lobe measures 4.4 cm SI x 2.6 cm ML x 1.7 cm AP and the isthmus measures 3.6 cm SI x 1.2 cm ML x 0.7 cm AP. The external surfaces have fibrous adhesions. No parathyroid glands or lymph nodes are identified grossly. The right lobe contains a well delineated, firm, query calcified nodule that measures 1.0 cm SI x 1.7 cm ML x 0.9 cm AP. The left lobe contains two well defined, nodules that measure from 0.3 cm SI x 0.3 cm ML x 0.2 cm AP to 2.1 cm SI x 2.1 cm ML x 1.6 cm AP. There is a well delineated nodule in the medial right lobe and isthmus that measures 0.8 cm SI x 0.5 cm ML x 0.6 cm AP. The remainder of the thyroid tissue is grossly unremarkable. One piece of tumor from the left nodule, one piece of tumor from the right nodule, and one piece of normal thyroid from the left lobe are stored frozen. The remainder of the specimen is submitted as follows:

1A-1H right lobe, superior to inferior

1I-1K isthmus

1L-1U left lobe, superior to inferior

Source: NCI Genomic Data Commons file 7a4770b1-8ee1-4528-9db6-39c85cbe7140 (TCGA-EM-A22I.5403706A-C20F-4EB1-9AAF-DDE37DF704C2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).